Surgical pathology report (de-identified scan), TCGA case TCGA-3C-AALJ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Columbia University, specimen TCGA-3C-AALJ-01A (Primary Tumor).

[page 1 of 3]
Name: [REDACTED]
MRN: [REDACTED]
D.O.B. (Age:)
Sex: F
Location:

Path No.: [REDACTED]
Date Obtained:
Date Received:
Physician:

SURGICAL PATHOLOGY

SPECIMEN:

Breast, right, skin sparing modified radical mastectomy

*ICD-O-3
Carcinoma, infiltrating duct NOS
Site (R) Breast C50.9 8500/3
path (R) Breast, midline C50.8
W 8/11/14*

DIAGNOSIS(ES):

Breast, right, skin sparing modified radical mastectomy:

Invasive ductal carcinoma, poorly differentiated (Modified Scarff Bloom Richardson Score 3+3+2=8/9),
multifocal, with lymphatic invasion.

Metastatic carcinoma in 1/23 axillary lymph nodes (See microscopic description)

pT2N1

CLINICAL INFORMATION: Right breast cancer.

GROSS DESCRIPTION:

The specimen is received unfixed in a container labeled with the patient's name and "Right breast mastectomy". It consists of a right modified mastectomy specimen measuring 24.0 x 20.0 x 5.2 cm. A suture is noted indicating the axillary tail. The overlying skin measures 14.5 x 8.0 cm. The nipple is mobile and everted. An underlying mass is palpable in the 6 o'clock position. The deep (fascial) margin is inked black and the remaining margins are inked yellow. The axillary tissue measures 11.0 x 6.5 x 2.0 cm. Multiple lymph nodes are palpable within it measuring from 0.5 cm to 1.7 cm in greatest dimension. The lymph nodes are dissected, proceeding from the breast toward the axilla.

The specimen is serially sectioned at closely spaced intervals revealing a firm, poorly circumscribed, white and focally hemorrhagic mass measuring 3.5 x 3.0 x 2.0 cm located in the inferior aspect of the specimen (6 o'clock position). The mass comes to within 0.8 cm of the skin and 3.0 cm of the deep margin. A second firm, well circumscribed mass measuring 0.7 x 0.5 x 0.5 is also identified located 0.8 cm from the skin, 2.4 cm from the deep margin and 2.0 cm from the previously described mass, superiorly. The parenchyma superior and lateral to both masses is firm, lobulated and gritty over an area measuring 4.0 x 3.5 x 2.0 cm. The remaining tissue is composed of a moderate amount of breast tissue and a moderate amount of yellow fatty tissue. Representative sections are submitted in 37 cassettes labeled A1-A37. Please note: The specimen was placed in formalin at

LEGEND:

A1-A3 = Nipple
A4 = Deep margin closest to main mass
A5 = Main mass with closest skin
A6-A8 = Main mass
A9-A10 = Smaller mass
A11 = Smaller mass with closest skin
A12 = Deep margin closest to smaller mass

[page 2 of 3]
A13-A18 = Gritty area surrounding masses
A19-A20 = Upper inner quadrant
A21-A22 = Lower inner quadrant
A23-A24 = Lower outer quadrant
A25-A26 = Upper outer quadrant
A27 = Bisected lymph node closest to breast
A28 = 3 intact nodes
A29 = 3 intact nodes
A30 = 1 bisected node
A31 = 1 bisected node
A32 = 1 bisected node
A33 = 2 intact nodes
A34 = 4 intact nodes
A35 = 3 intact nodes
A36 = 2 intact nodes
A37 = 1 bisected node at high point.

MICROSCOPIC DESCRIPTION:

- I. TYPE OF SPECIMEN: Right modified radical mastectomy
- II. LOCATION OF THE TUMOR: Central (6 o'clock), extending into lower inner and outer quadrants.
- III. TYPE OF NEOPLASM: Carcinoma, invasive, ductal, with central scar and micropapillary features.

Poorly Differentiated, Total score 8
(Tubule Score 3, Nuclear Grade Score 3, Mitotic Score 2)

Ductal carcinoma in situ, nuclear grade 3, multifocal 30 %

Intraductal papillary subtype
Intraductal micropapillary subtype
Intraductal solid subtype
Intraductal comedo subtype

Necrosis is present within the intraductal carcinoma

Lobular neoplasia is not present

- IV. GROSS/MICRO FINAL INVASIVE TUMOR SIZE INTERPRETATION: 3.5 x 3.0 x 2.0 cm. (In addition, separate foci of invasive carcinoma are seen superior to and lateral to the main mass these have a similar histology; the largest such focus measures 1.5cm on the slide.

- VI. VASCULAR SPACE INVASION: Present in lymphatics
- VII. CALCIFICATION: Present in malignant areas
- VIII. NIPPLE: Present, uninvolved by cancer
- IX. SKIN: Present, uninvolved by cancer
- X. ADJACENT BREAST TISSUE: Cystic disease, proliferative with atypia
- XI. MARGINS: Negative
- XII. AXILLARY LYMPH NODES:
- XII. AXILLARY LYMPH NODES:

[page 3 of 3]
TOTAL: 23

HIGH POINT: 1

XIII. POSITIVE LYMPH NODES:

XIII. POSITIVE LYMPH NODES:

TOTAL: 1

LEVEL I: 1 (adjacent to breast)

EXTRANODAL EXTENSION: Present

XIV. PECTORAL MUSCLE: No pectoral muscle identified

XV. PATHOLOGIC STAGING (pTNM) AJCC 7th Edition: *Reflects staging only of the current specimen. Ultimate staging responsibility rests with the primary physician.*

pT2: Tumor more than 2.0 cm but not more than 5.0 cm in greatest dimension

pN1a: Metastasis in 1 to 3 axillary lymph nodes (at least 1 tumor deposit greater than 2.0 mm)

This report has been reviewed electronically and signed on by

Interpreted by: Attending:

The diagnosis was rendered by the attending pathologist.

Note: Immunochemistry testing performed at was developed and its performance characteristics determined by the

These tests were interpreted in conjunction with external positive and internal negative controls, unless otherwise noted. It has not been cleared or approved by the US FDA. This test is used for clinical purposes only. It should not be regarded as investigational or for research.

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 2d4df18c-bef2-4136-a50c-96c5b110778f (TCGA-3C-AALJ.265E5A9A-64FD-4B86-89BC-5E89F253C118.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).